Somatic mutation profile of tumor specimen TCGA-MT-A67A-01A (aliquot TCGA-MT-A67A-01A-11D-A30E-08) from TCGA case TCGA-MT-A67A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 85.3 years (31,161 days).
Specimen TCGA-MT-A67A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49ed69f2-c115-4ca8-bac9-fbf056c8030c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A67A-10A (Blood Derived Normal), aliquot TCGA-MT-A67A-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88809d6a-4a73-4905-89b5-f02b4d9fb3f5

The open-access MAF lists 120 somatic variants for this specimen: 90 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 25, Nonsense Mutation 8, Frame Shift Del 4, Frame Shift Ins 3, In Frame Del 3, Splice Region 2, RNA 1, 3'UTR 1, Splice Site 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- NFE2L2 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101229406, COSV67960170, COSV67961004; called by muse, mutect2, varscan2
- TP63 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs121908849, CM013065, CM110083, COSV53200099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs141745439, COSV57052794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs145170042; called by muse, mutect2, varscan2
- ANXA6 | c.1443T>G p.Y481* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100636998; called by muse, mutect2, varscan2
- ARHGEF1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1555846523, COSV100529099; called by muse, mutect2
- ARHGEF17 | c.1136C>G p.S379W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV99736186; called by muse, mutect2, varscan2
- ARMC3 | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958549; called by muse, mutect2, varscan2
- ATP13A2 | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564643512, COSV58698687; called by muse, mutect2, varscan2
- ATP8B1 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV99377549; called by muse, mutect2, varscan2
- C2orf68 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs369096715; called by muse, mutect2, varscan2
- CFAP54 | c.7414T>C p.S2472P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100733273; called by muse, mutect2, varscan2
- CHL1 | c.1196A>G p.Y399C (on ENST00000397491 / NM_001253387.1; = p.Y415C on NM_006614.4) | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99851718; called by muse, mutect2, varscan2
- CHRNA4 | c.661A>G p.R221G | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV100937454; called by muse, mutect2, varscan2
- COL6A5 | c.6157A>G p.N2053D (on ENST00000312481; = p.N2049D on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99593889; called by muse, mutect2, varscan2
- CORO1C | c.750G>A p.P250= | Splice Region (SNP) | VAF 26/147 reads (18%) | catalogued as rs762555895, COSV99776061; called by muse, mutect2, varscan2
- CUX1 | c.1477G>A p.E493K (on ENST00000437600 / NM_181500.4; = p.E495K on NM_001913.5) | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.121); catalogued as COSV99476246; called by muse, mutect2, varscan2
- CYP4F3 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99658445; called by muse, mutect2, varscan2
- CYTH3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV100641528; called by muse, mutect2, varscan2
- DMXL1 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1459725642, COSV100224447; called by muse, mutect2
- EIF3G | c.714C>G p.N238K | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.115); catalogued as COSV53451325, COSV99461585; called by muse, mutect2, varscan2
- EPB41L2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs374441396; called by muse, mutect2, varscan2
- FOXM1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700879; called by muse, mutect2, varscan2
- GBA3 | c.912dup p.A305Cfs*29 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | catalogued as rs776182136; called by mutect2, varscan2
- GK | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100970925; called by muse, mutect2, varscan2
- GLDC | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs386833556, CM043947, COSV58679455, COSV58679640; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- H3-4 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV64210688; called by muse, mutect2, varscan2
- IRX1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs758355953, COSV100116559; called by muse, mutect2, varscan2
- KAT2A | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99288384; called by muse, mutect2, varscan2
- KIDINS220 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876083; called by muse, mutect2, varscan2
- KMT2D | c.4843C>T p.R1615* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | catalogued as CM105487, COSV56420226; called by muse, mutect2, varscan2
- LAMA4 | c.1665A>G p.I555M (on ENST00000230538 / NM_001105206.3; = p.I548M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV100038893; called by muse, mutect2, varscan2
- LAMB2 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs144783830, COSV100026346; called by muse, mutect2, varscan2
- LINGO1 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1327849277, COSV100796453; called by muse, mutect2, varscan2
- LIPE | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs138508614; called by muse, mutect2, varscan2
- MAGEB6B | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.277); catalogued as rs371855458; called by muse, mutect2, varscan2
- MAML3 | c.2859G>A p.M953I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101558475; called by muse, mutect2, varscan2
- MAN2B1 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs755553683, COSV99667155; called by muse, mutect2, varscan2
- MDC1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs61748587, COSV100902977; called by muse, mutect2, varscan2
- NOTCH1 | c.1650C>A p.Y550* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV104374504, COSV53099012, COSV53109473; called by muse, mutect2, varscan2
- NOTCH2 | c.7049G>C p.S2350T | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs771816232, COSV99865478; called by muse, mutect2, varscan2
- NRXN3 | c.536C>A p.T179N (on ENST00000557594 / NM_001272020.2; = p.T811N on NM_004796.6) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99820402; called by muse, mutect2, varscan2
- NUP98 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100262908; called by muse, mutect2, varscan2
- OR2T2 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as rs780020291, COSV100737738, COSV61618434; called by muse, mutect2, varscan2
- OR4C11 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100155403; called by muse, mutect2, varscan2
- PCDH19 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99720326; called by muse, mutect2, varscan2
- PFKM | c.1507A>G p.T503A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV100402597; called by muse, mutect2, varscan2
- PHF20 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100180512; called by muse, mutect2, varscan2
- PTPRB | c.2779A>T p.N927Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV99718175; called by muse, mutect2, varscan2
- PYDC1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs775103425, COSV57251675; called by muse, mutect2, varscan2
- RICTOR | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57121664, COSV57126162; called by muse, mutect2, varscan2
- RIPPLY3 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV100289386; called by muse, mutect2, varscan2
- RSPH10B | c.1703C>G p.A568G | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100521359; called by muse, mutect2, varscan2
- SAFB | c.2303C>G p.S768* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99412485, COSV99413041; called by muse, mutect2, varscan2
- SCAF4 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1490940922, COSV54586352, COSV99741800; called by muse, mutect2, varscan2
- SIPA1L2 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs576412635, COSV99477193, COSV99477610; called by muse, mutect2, varscan2
- SLC25A25 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as rs750278943, COSV100895351; called by muse, mutect2, varscan2
- SOX9 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.98); catalogued as COSV99818585; called by muse, mutect2, varscan2
- SPTBN4 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58951460, COSV58952902; called by muse, mutect2, varscan2
- SSPOP | n.15119G>C | Splice Region (SNP) | VAF 83/208 reads (40%) | catalogued as COSV100947696; called by muse, mutect2, varscan2
- STAG3 | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs747177515, COSV100426089; called by muse, mutect2, varscan2
- SVIL | c.6370C>T p.H2124Y (on ENST00000355867 / NM_021738.3; = p.H1698Y on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV100881423; called by muse, mutect2, varscan2
- SYNE2 | c.9241C>G p.R3081G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100648133; called by muse, mutect2, varscan2
- SYNPO2L | c.1829G>A p.R610H (on ENST00000394810 / NM_001114133.3; = p.R386H on NM_024875.5) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65738529; called by muse, mutect2, varscan2
- TADA2B | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs1241546248, COSV99380704; called by muse, mutect2, varscan2
- TAS2R20 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1455695679, COSV101115186, COSV101115500; called by muse, mutect2
- TLK1 | c.2228C>A p.S743Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV62633921; called by muse, mutect2, varscan2
- TMED10 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV57846726; called by muse, mutect2, varscan2
- TMEM43 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as rs147336367; ClinVar: uncertain significance; called by muse, mutect2
- TP53BP1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 101/277 reads (36%) | catalogued as COSV99780957; called by muse, mutect2, varscan2
- TRIM48 | c.674G>T p.*225Lext*167 | Nonstop Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101338309; called by muse, mutect2, varscan2
- TSPYL5 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1389732110, COSV59072251; called by muse, mutect2, varscan2
- TTLL4 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99293538; called by muse, mutect2, varscan2
- UBQLN3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs370344868, COSV61163760; called by muse, mutect2, varscan2
- WTAP | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs373161821; called by muse, mutect2, varscan2
- ZNF292 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100370749; called by muse, mutect2, varscan2
- ZSCAN5A | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs1251988547, COSV54223291, COSV99570408; called by muse, mutect2, varscan2
- CAP1 | c.1120_1139del p.N374Gfs*4 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- DOP1A | c.5232+2dup p.X1744_splice | Splice Site (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- FAT1 | c.7183del p.Y2395Mfs*15 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1640dup p.L547Ffs*4 (on ENST00000281708 / NM_001349798.2; = p.L467Ffs*4 on NM_018315.5) | Frame Shift Ins (INS) | VAF 21/122 reads (17%) | called by mutect2, pindel, varscan2
- KMT2B | c.7855_7857del p.K2619del | In Frame Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- PLIN4 | c.2950_2968delinsC p.F984_A990delinsP (on ENST00000301286; = p.F999_A1005delinsP on NM_001367868.2) | In Frame Del (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2*
- SCAF4 | c.1282_1283del p.M428Vfs*2 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- SLC44A4 | c.2120_2122del p.K707del | In Frame Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- SPPL2A | c.1258del p.I420Lfs*29 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- TRDC | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VEZF1 | c.732_736dup p.H246Lfs*4 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- ADGRF5 | c.3225G>A p.Q1075= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV99346030; called by muse, mutect2, varscan2
- AMPD2 | c.270G>A p.P90= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs139217835, COSV56649375; called by muse, mutect2, varscan2
- AOPEP | c.1713C>A p.I571= (on ENST00000375315 / NM_001193329.1; = p.I472= on NM_032823.5) | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99950291; called by muse, mutect2
- AP4E1 | c.1044T>G p.P348= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99956880; called by muse, mutect2, varscan2
- BOD1L1 | c.3907C>T p.L1303= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99239897; called by muse, mutect2, varscan2
- CPB2 | c.1068C>T p.G356= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs766954397, COSV99473209; called by muse, mutect2, varscan2
- DAB2IP | c.1578C>T p.L526= (on ENST00000408936; = p.L498= on NM_032552.3) | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as COSV99405948; called by muse, mutect2, varscan2
- DCTN1 | c.693A>G p.L231= | Silent (SNP) | VAF 116/481 reads (24%) | catalogued as rs1291091043, COSV100721000; called by muse, mutect2, varscan2
- DNMT1 | c.3867C>T p.R1289= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs760372702, COSV100532739; called by muse, mutect2, varscan2
- ELOA | c.1947T>C p.Y649= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV101403792; called by muse, mutect2, varscan2
- F3 | c.15C>T p.A5= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100474352; called by muse, mutect2
- GATA3 | c.861C>T p.C287= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs746122348, COSV60521897; called by muse, mutect2, varscan2
- HPR | c.111C>G p.P37= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99930970; called by muse, mutect2, varscan2
- IL10RB | c.858G>A p.S286= | Silent (SNP) | VAF 52/191 reads (27%) | catalogued as rs760719286, COSV51616402; called by muse, mutect2, varscan2
- LRRC32 | c.675G>A p.L225= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99477114; called by muse, mutect2, varscan2
- MCM2 | c.567G>A p.A189= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as rs772343227, COSV99413285; called by muse, mutect2, varscan2
- NUDT10 | c.213A>T p.G71= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- OGDH | c.1260G>A p.V420= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV99759263; called by muse, mutect2, varscan2
- OR2T33 | c.459C>T p.D153= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as rs764565834, COSV58817401, COSV58817854; called by muse, mutect2, varscan2
- RHAG | c.399G>C p.L133= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1384781030, COSV100006712; called by muse, mutect2
- RYR2 | c.8511G>A p.L2837= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100771934; called by muse, mutect2, varscan2
- SLC46A1 | c.957G>T p.L319= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100398129; called by muse, mutect2, varscan2
- TCF21 | c.372G>A p.A124= | Silent (SNP) | VAF 57/216 reads (26%) | catalogued as rs201214778, COSV99399490; called by muse, mutect2, varscan2
- ZBTB11 | c.2682T>C p.A894= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100465637; called by muse, mutect2, varscan2
- ZNF692 | c.447C>T p.S149= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs375885347; called by muse, mutect2, varscan2
- GABRR2 | c.-50C>T | 5'UTR (SNP) | VAF 79/298 reads (27%) | catalogued as COSV68764328, COSV68764484; called by muse, mutect2, varscan2
- LINC01565 | n.1152del | RNA (DEL) | VAF 18/101 reads (18%) | catalogued as rs943530001; called by pindel, varscan2
- LST1 | c.*57G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53000999, COSV99279148; called by muse, mutect2, varscan2
- MAGEA4 | chrX:151912531 T>C | 5'Flank (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- ZNF773 | chr19:57513061 G>A | 3'Flank (SNP) | VAF 5/20 reads (25%) | catalogued as rs370028083; called by muse, mutect2, varscan2
